FM case AD3510 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Germ Cell Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/1466baab-5cc7-4ab9-b6de-0fc9bb3969b6

Female, 64.7 years: Germ cell tumor, NOS (ICD-O-3 9064/3) of the ovary; metastasis biopsied or resected from the spleen. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
